Gene-level copy-number profile of tumor specimen C3L-00967-04 from CPTAC case C3L-00967, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.8 years (25,489 days).
Specimen C3L-00967-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6f6b19f-847d-4248-985f-66c8454f0f5b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00967-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/ef717cd8-f2a2-49a6-bb53-623da90acd69

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 15; copy number 2: 2,657; copy number 3: 103; copy number 4: 32,957; copy number 5: 1,402; copy number 6: 11,153; copy number 7: 1,400; copy number 8: 4,822; copy number 9: 811; copy number 10: 3,006; copy number 11: 24; copy number 12: 13; copy number 13: 14.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,868 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 10–11 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 13: TRGC2.
- chr7:38,256,337–38,330,935, 13 genes, copy number 13 (within-gene range 8–13): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr8:123,041,968–123,275,541, 13 genes, copy number 12 (within-gene range 8–12): TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P.
- chr18:20,946,906–36,067,576, 240 genes, copy number 9 (broad region; genes not listed).
- chr18:38,655,209–80,247,514, 571 genes, copy number 9 (broad region; genes not listed).
- chr20:36,651,766–36,746,090, 1 gene, copy number 10 (within-gene range 6–10): NDRG3.
- chr20:36,751,791–60,653,784, 505 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
